Gene-level copy-number profile of tumor specimen HCM-CSHL-0383-C18-01A from HCMI case HCM-CSHL-0383-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: G2; Age at diagnosis: 51.4 years (18,766 days).
Specimen HCM-CSHL-0383-C18-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 906e42bb-43cd-42c6-b06e-f87fe88b17c7.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-CSHL-0383-C18-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,718 have no estimate.
https://portal.gdc.cancer.gov/files/a7248553-decf-449d-866a-1d1cbff2b805

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 6; copy number 1: 58; copy number 2: 23,879; copy number 3: 21,390; copy number 4: 9,173; copy number 5: 2,841; copy number 6: 217; copy number 7: 1,031; copy number 8: 206; copy number 12: 8; copy number 13: 20; copy number 15: 4; copy number 23: 30; copy number 24: 3; copy number 31: 4; copy number 32: 31; copy number 47: 4.

Homozygous deletions (total copy number 0; autosomes only): 6 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:7,881,392–7,896,716, 3 genes: DEFB103A, HSPD1P2, DEFB4A.
- chr9:61,581,813–61,582,675, 1 gene: AL935212.3.
- chr17:18,426,861–18,442,895, 2 genes: KRT17P2, KRT16P1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 3,698 genes in 26 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:11,869–522,928, 25 genes, copy number 5–6: DDX11L1, WASH7P, MIR6859-1, MIR1302-2HG, MIR1302-2, FAM138A, OR4G4P, OR4G11P, OR4F5, AL627309.1, AL627309.3, CICP27, AL627309.6, AL627309.7, AL627309.2, RNU6-1100P, AP006222.2, RPL23AP24, AL732372.1, AL732372.2, WBP1LP7, OR4F29, CICP7, AL732372.3, U6.
- chr1:587,629–594,768, 1 gene, copy number 6: AC114498.1.
- chr1:631,074–632,616, 2 genes, copy number 6 (within-gene range 2–6): MTCO1P12, AC114498.2.
- chr1:633,535–634,922, 3 genes, copy number 6 (within-gene range 2–6): MTATP8P1, MTATP6P1, MTCO3P12.
- chr1:12,791,397–12,922,660, 10 genes, copy number 5: PRAMEF1, LINC01784, PRAMEF11, PRAMEF30P, HNRNPCL1, PRAMEF2, PRAMEF4, PRAMEF10, PRAMEF7, RNU6-1072P.
- chr1:143,419,625–143,739,506, 15 genes, copy number 6: AC239859.5, RNA5SP533, AC239859.3, AC239859.4, NKAIN1P1, AC239859.2, LINC02799, AC239859.1, NBPF17P, PFN1P12, RNU1-114P, RNVU1-17, RNVU1-23, RNVU1-18, AC239800.2.
- chr2:242,088,633–242,175,634, 4 genes, copy number 5: LINC01881, CICP10, SEPTIN14P2, RPL23AP88.
- chr4:68,509,441–68,616,137, 4 genes, copy number 7: UGT2B29P, UGT2B17, AC147055.2, AC147055.4.
- chr4:68,646,597–68,670,652, 1 gene, copy number 7: UGT2B15.
- chr5:140,071,312–141,907,939, 136 genes, copy number 7 (broad region; genes not listed).
- chr7:37,032–9,189,857, 204 genes, copy number 5 (broad region; genes not listed).
- chr7:69,026,433–70,838,013, 11 genes, copy number 5: AC104688.1, RNU6-832P, AC092100.1, AC069280.1, MTCO2P25, MTCO1P25, RNU6-229P, Y_RNA, CT66, AUTS2, AC073873.1.
- chr8:37,908,738–43,085,788, 124 genes, copy number 5 (broad region; genes not listed).
- chr8:46,028,804–140,458,579, 1,297 genes, copy number 5 (broad region; genes not listed).
- chr9:64,810,865–64,889,063, 4 genes, copy number 5–7: BNIP3P4, AL359955.1, AC125634.1, RNU6-1293P.
- chr10:52,972,612–55,746,908, 17 genes, copy number 5–6: LINC02672, SNRPEP8, AC036101.1, RNA5SP318, AL365496.1, PCDH15, RNU6-687P, AL353784.1, NEFMP1, MIR548F1, AC051618.1, AC016822.1, AL355314.1, AL355314.2, MTRNR2L5, GAPDHP21, AC069545.1.
- chr10:68,698,500–69,692,452, 38 genes, copy number 5: AL513534.2, AL513534.3, CCAR1, Y_RNA, SNORD98, AL513534.1, STOX1, RNU6-697P, DDX50, RNU6-571P, DDX21, KIFBP, MED28P1, ACTBP14, SRGN, Metazoa_SRP, VPS26A, RPS12P17, SUPV3L1, AL596223.1, HKDC1, AL596223.2, HK1, RPS15AP28, TACR2, ATP5MC1P7, TSPAN15, AC016821.1, TMEM256P1, NEUROG3, AL450311.1, MTATP6P23, MTCO2P23, MTCO1P23, MTND2P15, MTND1P20, FAM241B, LINC02651.
- chr10:73,005,833–80,646,560, 198 genes, copy number 5–12 (within-gene range 5–13) (broad region; genes not listed).
- chr13:20,564,708–22,706,206, 49 genes, copy number 12–47: AL590096.1, IFT88, SLC35E1P1, RNU2-7P, AL161772.1, IL17D, AL512652.2, EEF1AKMT1, RANP8, AL512652.1, XPO4, CNOT4P1, HNRNPA1P30, PPIAP27, RPSAP54, LATS2, LATS2-AS1, RNU4-9P, RPS12P23, IPPKP1, AL161613.1, SNORD27, SAP18, SKA3, MRPL57, AL158032.1, LINC01046, ESRRAP2, AL158032.2, MIPEPP3, LINC00539, GRK6P1, GAPDHP52, RNA5SP25, ZDHHC20, ZDHHC20-IT1, H2BP6, MICU2, FNTAP2, RNU6-59P, RPS7P10, FGF9, RN7SL766P, LINC00424, LINC00540, NME1P1, MTND3P1, FTH1P7, DDX39AP1.
- chr13:26,755,200–28,718,970, 48 genes, copy number 13–24: GPR12, FGFR1OP2P1, AL160035.1, RPS21P8, RPS20P32, USP12, AL158062.1, USP12-AS1, USP12-AS2, LINC02340, LINC00412, RPL21, SNORD102, SNORA27, RASL11A, RNU6-70P, LINC01079, RNY1P1, GTF3A, MTIF3, RNU6-63P, LNX2, POLR1D, AL136439.1, NPM1P4, GSX1, PLUT, RNU6-73P, PDX1, ATP5F1EP2, LINC00543, CDX2, URAD, RN7SL272P, FLT3, KATNBL1P1, CHCHD2P8, PAN3-AS1, PAN3, EEF1A1P3, RNU6-82P, FLT1, AL139005.1, EIF4A1P7, Y_RNA, POMP, SLC46A3, RNU6-53P.
- chr13:114,314,482–114,337,626, 2 genes, copy number 5: CHAMP1, LINC01054.
- chr17:29,560,547–29,707,090, 1 gene, copy number 5 (within-gene range 2–5): ABHD15-AS1.
- chr17:29,573,475–30,186,475, 29 genes, copy number 5: GIT1, ANKRD13B, AC104564.4, CORO6, AC104564.2, SSH2, AC104564.1, RNU6-920P, AC104564.5, RPL21P123, AC023389.1, AC023389.2, SNORA70, RPL9P30, AC104982.2, AC104982.1, EFCAB5, AC104982.3, RNY4P13, AC104996.3, AC104996.1, AC104996.2, AC104984.2, NSRP1, hsa-mir-423, MIR423, MIR3184, AC104984.3, AC104984.5.
- chr17:32,083,179–32,906,584, 40 genes, copy number 5: AC090616.2, AC090616.5, AC090616.1, WDR45BP1, AC116407.2, AC116407.1, RHOT1, ARGFXP2, AC116407.4, AC116407.3, UBL5P2, RHBDL3, AC026620.1, AC005899.4, C17orf75, AC005899.3, OOSP1P2, MIR632, ZNF207, AC005899.6, AC005899.7, AC005899.5, AC005899.8, AC005899.1, AC005899.2, PSMD11, Y_RNA, CDK5R1, MYO1D, AC079336.5, AC079336.7, AC079336.2, AC079336.1, AC079336.6, AC079336.4, AC079336.3, AC025211.1, Y_RNA, AC084809.1, AC084809.2.
- chr20:87,250–64,327,972, 1,401 genes, copy number 5–8 (broad region; genes not listed).
- chr21:8,996,496–13,016,692, 34 genes, copy number 5: CR392039.3, CDRT15P9, CR392039.4, TEKT4P2, SOWAHCP2, CR392039.2, CR381653.1, SNX18P12, CR381653.2, NCOR1P4, AC124864.1, AC124864.2, U1, LINC01667, AC018692.2, RN7SL52P, SNORA70, AC018692.1, CR382285.1, CR382285.2, CR382287.1, CDRT15P8, AP003900.1, EIF3FP1, VN1R7P, AF254983.2, BAGE2, AF254983.1, TPTE, CYCSP41, SLC25A15P4, AF254982.1, IGHV1OR21-1, AP001464.1.

Autosomal genes at a single copy (total copy number 1): 15. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
